Somatic mutation profile of tumor specimen TARGET-30-PARGZK-01A (aliquot TARGET-30-PARGZK-01A-01D) from TARGET case TARGET-30-PARGZK, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 4.3 years (1,583 days).
Specimen TARGET-30-PARGZK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e166b9de-0592-4dd2-964a-a7ec6cebacd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARGZK-10A (Blood Derived Normal), aliquot TARGET-30-PARGZK-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/95c191cd-c079-45f5-b7a9-d3bc50f598ac

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC9 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.43); catalogued as COSV63022228; called by muse, varscan2
- CRYBG1 | c.2012C>A p.P671Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64813167; called by muse, mutect2, varscan2
- FGF3 | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 31/74 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV61926330; called by muse, mutect2, varscan2
- FCHO1 | c.1155C>A p.G385= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as rs1196358868, COSV53183542; called by muse, mutect2, varscan2
- NSUN4 | c.909C>T p.G303= | Silent (SNP) | VAF 42/84 reads (50%) | catalogued as COSV61063472; called by muse, mutect2, varscan2
